Surgical pathology report (de-identified scan), TCGA case TCGA-2A-A8W3, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Memorial Sloan Kettering Cancer Center, specimen TCGA-2A-A8W3-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

History of Gleason 4+5=9 in 1/12 cores left base, PSA 7.13.

Specimens Submitted:

- 1: Prostate and seminal vesicles
- 2: Left pelvic lymph node
- 3: Right pelvic lymph node
- 4: Peri prostatic fat

DIAGNOSIS:

1. Prostate and seminal vesicles:

Part # 1

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:4

Secondary Gleason grade:5

Total Gleason score:9

Tumor Location:

Involves Left posterior

Dominant tumor mass located in: left posterior, apex to base

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Not Identified

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Established extracapsular extension

The location of the extracapsular extension is left posterior base

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

ICD O-3

Adenocarcinoma, NOS 8140/3

Site: Prostate NOS C61.9

7/23/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT3a (extracapsular extension)

2. Left pelvic lymph node:

Part # 2

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

3. Right pelvic lymph node:

Part # 3

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 2

4. Peri prostatic fat, biopsy

- Benign fibroadipose tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Prostate and seminal vesicles".

It consists of a prostate and seminal vesicles.

The total weight is 63.0 grams.

The prostate measures 4.5cm from apex to base, 4.5cm transversely, and 4.0cm from anterior to posterior.

The right and left seminal vesicles measure 6.0 x 2.0 and 6.0 x 2.0 cm, respectively.

The external surface of the prostate is smooth.

The prostate is inked (right=green, left=blue) and fixed in formalin overnight.

The prostate is serially cut from apex to base at approximately 3-4 mm intervals.

The prostate is entirely submitted.

Summary of Sections:

RA-right apical margin

LA-left apical margin

BN-bladder neck margin

RSV-right seminal vesicle

LSV-left seminal vesicle

A-H -serial sections of prostate (apex to base)

2). Received in formalin labeled "left pelvic node" is a 4.2 x 1.1 x 0.9 cm fragment of yellow-tan adipose tissue containing a 3.1 x 1.0 x 0.5 cm pink-tan lymph node and a 0.3 cm yellow-tan possible lymph node. The lymph nodes are entirely submitted with the large lymph node been serially sectioned and submitted in cassettes.

Summary of sections:

LN - lymph nodes

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

LNS - single lymph node serially sectioned

3). Received in formalin labeled "right pelvic lymph node" is a 5 x 3.5 x 1.5 cm aggregate of yellow-tan adipose tissue containing multiple lymph nodes ranging from 0.5 to 1.9 cm in greatest diameter. Lymph nodes are entirely submitted with the largest lymph node serially sectioned and submitted in multiple.

Summary of sections:

LN - lymph nodes

LNS - lymph nodes serially sectioned

4). Received in formalin labeled "periprosthetic fat" is a 5.1 x 3.9 x 1.1 cm fragment of yellow tissue. No lymph nodes are identified. Representative sections are submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Prostate and seminal vesicles

Blocks	Block Designation	PCs
1	A	1
1	B	1
1	BN	1
1	C	1
1	D	1
1	E	1
1	F	1
1	G	1
1	H	1
1	LA	1
1	LSV	1
1	RA	1
1	RSV	1

Part 2: Left pelvic lymph node

Blocks	Block Designation	PCs
1	LN	1
3	LNS	6

Part 3: Right pelvic lymph node

Blocks	Block Designation	PCs
1	LN	3
3	LNS	4

Part 4: Peri prostatic fat

Blocks	Block Designation	PCs
1	U	1

Criteria	hw 12/2/13	Yes	No

Source: NCI Genomic Data Commons file 7481d698-0224-4bf5-a776-98b0cb13a789 (TCGA-2A-A8W3.EC74AC3A-610D-46E0-A4DA-1904E42E1EF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).